Somatic mutation profile of tumor specimen ALCH-AEOV-TTP1-A (aliquot ALCH-AEOV-TTP1-A-1-0-D-A636-36) from ALCHEMIST case ALCH-AEOV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 72.1 years (26,348 days).
Specimen ALCH-AEOV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fc8b84d-ed5f-4326-a09a-89d96dc5395a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEOV-NB1-A (Blood Derived Normal), aliquot ALCH-AEOV-NB1-A-1-0-D-A635-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2ef60eb-6525-4754-b040-872d31fc3e32

The open-access MAF lists 320 somatic variants for this specimen: 213 protein-altering or splice-affecting, 71 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 180, Silent 71, Nonsense Mutation 24, Intron 18, 5'UTR 6, 3'UTR 5, Frame Shift Del 4, RNA 4, 5'Flank 3, Splice Region 2, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 81/546 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.3269G>T p.R1090L (on ENST00000404938 / NM_001163941.2; = p.R645L on NM_178559.6) | Missense Mutation (SNP) | VAF 94/396 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51707143; called by muse, mutect2, varscan2
- AC100868.1 | c.1444G>T p.G482W | Missense Mutation (SNP) | VAF 49/387 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1305605407, COSV99226747; called by muse, mutect2, varscan2
- ADGRB3 | c.2009G>T p.G670V | Missense Mutation (SNP) | VAF 49/259 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65408448; called by muse, mutect2, varscan2
- ANK1 | c.1406A>G p.D469G | Missense Mutation (SNP) | VAF 36/329 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV55886864; called by muse, mutect2, varscan2
- ANKIB1 | c.2611C>G p.L871V | Missense Mutation (SNP) | VAF 11/167 reads (7%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV56067219; called by muse, mutect2
- ANKRD36 | c.3313G>T p.D1105Y | Missense Mutation (SNP) | VAF 30/512 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.102); catalogued as rs1273440557; called by muse, mutect2
- ASTN1 | c.928C>A p.P310T | Missense Mutation (SNP) | VAF 83/573 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56069258; called by muse, mutect2, varscan2
- ATP6V0A1 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.85); catalogued as COSV99230542; called by muse, mutect2
- ATR | c.815C>G p.S272* | Nonsense Mutation (SNP) | VAF 41/252 reads (16%) | catalogued as COSV63390386; called by muse, mutect2, varscan2
- BMP2K | c.1669C>G p.Q557E | Missense Mutation (SNP) | VAF 21/332 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs765434750; called by muse, mutect2
- BMP6 | c.755C>A p.T252K | Missense Mutation (SNP) | VAF 44/418 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51660844; called by muse, mutect2, varscan2
- CACNA1E | c.5516C>T p.T1839I | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100701556; called by muse, mutect2, varscan2
- CHD1L | c.610A>T p.T204S | Missense Mutation (SNP) | VAF 46/470 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63614912; called by muse, mutect2
- CLDN9 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as rs1335740798; called by muse, mutect2, varscan2
- CRACD | c.1813G>T p.G605C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99949003; called by muse, mutect2, varscan2
- DBR1 | c.1207G>C p.E403Q | Missense Mutation (SNP) | VAF 24/305 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV99604328; called by muse, mutect2
- DDX59 | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 24/389 reads (6%) | catalogued as COSV58751288; called by muse, mutect2
- DNAH11 | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 60/930 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs10269832; called by muse, mutect2
- DNAH11 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 146/515 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1427462468, COSV60959423; called by muse, mutect2, varscan2
- DNAH17 | c.6952G>T p.E2318* | Nonsense Mutation (SNP) | VAF 9/84 reads (11%) | catalogued as COSV101102003; called by muse, mutect2, varscan2
- DNMT1 | c.2060A>G p.Q687R | Missense Mutation (SNP) | VAF 25/262 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.158); catalogued as rs774333932; ClinVar: uncertain significance; called by muse, mutect2
- DOC2A | c.655-3C>T | Splice Region (SNP) | VAF 4/28 reads (14%) | catalogued as rs370418043; called by mutect2, varscan2
- DPH7 | c.847G>T p.G283C | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775059220; called by mutect2, varscan2
- DSC2 | c.1604G>C p.R535T | Missense Mutation (SNP) | VAF 58/531 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99199472; called by muse, mutect2, varscan2
- DSC3 | c.1530dup p.L511Ifs*3 | Frame Shift Ins (INS) | VAF 69/450 reads (15%) | catalogued as rs1317680492; called by mutect2, pindel, varscan2
- FAT3 | c.5044del p.E1682Kfs*11 | Frame Shift Del (DEL) | VAF 30/191 reads (16%) | catalogued as COSV99964572; called by mutect2, pindel, varscan2
- FGF6 | c.450+1G>T p.X150_splice | Splice Site (SNP) | VAF 10/68 reads (15%) | catalogued as COSV57403562; called by muse, mutect2, varscan2
- FLG | c.419G>C p.R140T | Missense Mutation (SNP) | VAF 60/939 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.535); catalogued as COSV64237947; called by muse, mutect2
- FLG2 | c.2005G>C p.G669R | Missense Mutation (SNP) | VAF 35/563 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as COSV101166114; called by muse, mutect2
- FMO3 | c.1402C>A p.P468T | Missense Mutation (SNP) | VAF 39/340 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs758899175, COSV63008970; called by muse, mutect2, varscan2
- GARS1 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as rs1415948102; called by muse, mutect2
- GK2 | c.1524G>T p.M508I | Missense Mutation (SNP) | VAF 40/535 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV62626909; called by muse, mutect2
- HS6ST2 | c.1427G>T p.R476L | Missense Mutation (SNP) | VAF 49/410 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.893); catalogued as COSV63714351; called by muse, mutect2, varscan2
- HYDIN | c.7469C>T p.A2490V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs367546874; called by muse, mutect2, varscan2
- IGHV1-18 | c.287G>C p.S96T | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs551173574; called by muse, mutect2
- ITPRID1 | c.2345C>A p.S782Y | Missense Mutation (SNP) | VAF 77/241 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60071609; called by muse, mutect2, varscan2
- KIAA1549L | c.636G>T p.Q212H (on ENST00000321505; = p.Q509H on NM_012194.3) | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs759786781, COSV55782800; called by muse, mutect2, varscan2
- LHX2 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.574); catalogued as rs1231821859; called by muse, mutect2, varscan2
- LRRC7 | c.2649G>T p.W883C (on ENST00000651989 / NM_001370785.2; = p.W850C on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50434938, COSV99227651; called by muse, mutect2
- LRRTM4 | c.1237G>C p.A413P | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV101297465; called by muse, mutect2
- MARCHF10 | c.1141G>C p.D381H | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.635); catalogued as COSV60886428, COSV60890088; called by muse, mutect2
- MET | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 36/495 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.995); catalogued as COSV59262439; called by muse, mutect2
- MROH1 | c.951C>G p.I317M | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.467); catalogued as rs751083062; called by muse, mutect2, varscan2
- MROH2B | c.3862G>C p.E1288Q | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101270960, COSV68185545; called by muse, mutect2
- MYH3 | c.3246G>T p.K1082N | Missense Mutation (SNP) | VAF 30/536 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV56868225, COSV56871540; called by muse, mutect2
- MYOT | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 28/523 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53516196; called by muse, mutect2
- NEFM | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs949862142, COSV55331632, COSV55335031; called by muse, mutect2
- NOP53 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV54409249, COSV99622309; called by muse, mutect2, varscan2
- OPRL1 | c.521T>C p.I174T | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs750838900; called by muse, mutect2
- PCDH9 | c.394G>T p.V132F | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV60540228; called by muse, mutect2, varscan2
- PCDHB11 | c.1165C>G p.L389V | Missense Mutation (SNP) | VAF 34/346 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.743); catalogued as COSV61312587; called by muse, mutect2
- PGK1 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 40/578 reads (7%) | catalogued as COSV100965301; called by muse, mutect2
- PGK2 | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 22/292 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59163832; called by muse, mutect2
- PKD1L2 | c.1271G>T p.R424L | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs138937023; called by muse, mutect2, varscan2
- PKD1L3 | c.1486C>G p.R496G | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as COSV100626242, COSV58663888; called by muse, mutect2, varscan2
- PPP2R3A | c.2945G>A p.R982H | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748038542, COSV53860516; called by mutect2, varscan2
- RYR1 | c.4727C>G p.A1576G | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1216589090; called by muse, mutect2
- RYR2 | c.3247G>T p.E1083* | Nonsense Mutation (SNP) | VAF 11/73 reads (15%) | catalogued as COSV63686319; called by muse, mutect2, varscan2
- RYR2 | c.11881G>T p.D3961Y | Missense Mutation (SNP) | VAF 34/263 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63668496; called by muse, mutect2, varscan2
- SETMAR | c.1420G>C p.E474Q | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.771); catalogued as COSV99065518; called by muse, mutect2
- SLC22A16 | c.968C>G p.S323* | Nonsense Mutation (SNP) | VAF 41/492 reads (8%) | catalogued as COSV57927922; called by muse, mutect2
- SLC43A2 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as rs569789272; called by muse, mutect2, varscan2
- SLC6A2 | c.1211G>T p.W404L | Missense Mutation (SNP) | VAF 34/506 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV99574788; called by muse, mutect2
- SLCO1A2 | c.1148C>T p.T383I | Missense Mutation (SNP) | VAF 31/626 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV56597714; called by muse, mutect2
- STAC3 | c.592G>C p.D198H | Missense Mutation (SNP) | VAF 17/222 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV60415945; called by muse, mutect2
- SUB1 | c.35C>A p.S12Y | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV54083593; called by muse, mutect2
- SYNE1 | c.8511G>C p.E2837D (on ENST00000367255 / NM_182961.4; = p.E2844D on NM_033071.3) | Missense Mutation (SNP) | VAF 44/704 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs781699682; called by muse, mutect2
- TDRD15 | c.4005G>C p.L1335F | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.11); catalogued as rs1423002168; called by muse, mutect2
- TEX11 | c.955G>A p.E319K (on ENST00000344304; = p.E304K on NM_031276.3) | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs1312102683, COSV100721353; called by muse, varscan2
- TNFRSF21 | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 44/624 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV57281868; called by muse, mutect2
- TNRC6B | c.3905C>A p.S1302Y (on ENST00000454349 / NM_001162501.2; = p.S1192Y on NM_015088.3) | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100109870; called by muse, mutect2
- TP63 | c.1295T>C p.I432T | Missense Mutation (SNP) | VAF 87/857 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV99286139; called by muse, mutect2, varscan2
- UBA1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.912); catalogued as rs376327849, COSV60112305; called by muse, mutect2
- VPS13D | c.5923C>G p.Q1975E | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.149); catalogued as rs1268304486; called by muse, varscan2
- ZNF197 | c.1115G>A p.C372Y | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs746888796; called by muse, mutect2
- ZNF43 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 13/245 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.796); catalogued as rs923835849, COSV61683460, COSV61684890; called by muse, mutect2
- ZNF729 | c.1757C>A p.A586D | Missense Mutation (SNP) | VAF 37/502 reads (7%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.457); catalogued as rs878914670; called by muse, mutect2
- ZNF804A | c.2893C>A p.Q965K | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV56463790; called by muse, mutect2, varscan2
- ZNF804B | c.2860G>A p.E954K | Missense Mutation (SNP) | VAF 30/464 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs267601621, COSV100305218; called by muse, mutect2
- ABCC1 | c.1449G>T p.M483I | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- AC011005.1 | c.494C>A p.P165H | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- ADAM20 | c.589A>T p.S197C | Missense Mutation (SNP) | VAF 33/300 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ADAMTS19 | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ADGRF3 | c.2239T>G p.C747G (on ENST00000311519 / NM_001145168.1; = p.C548G on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADNP2 | c.2693A>T p.H898L | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGAP3 | c.419T>C p.L140P (on ENST00000622464; = p.L176P on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKAP9 | c.10750C>A p.Q3584K (on ENST00000359028; = p.Q3560K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/536 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.195); called by muse, mutect2
- AMER1 | c.131C>A p.P44Q | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD26 | c.2775A>T p.R925S | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.163); called by muse, mutect2
- ANKRD26 | c.1491G>T p.K497N | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2
- ARHGEF9 | c.1480T>A p.F494I | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.028); called by muse, mutect2
- ARID4A | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 40/564 reads (7%) | called by muse, mutect2
- ASPM | c.1785A>C p.E595D | Missense Mutation (SNP) | VAF 111/1006 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.038); called by muse, varscan2
- ATF6 | c.344A>T p.Q115L | Missense Mutation (SNP) | VAF 66/478 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- AXL | c.2615C>A p.T872K (on ENST00000301178 / NM_021913.5; = p.T863K on NM_001699.6) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BCORL1 | c.3770A>T p.E1257V | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.12); called by muse, mutect2
- CCL11 | c.255G>T p.M85I | Missense Mutation (SNP) | VAF 72/495 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CCT5 | c.1344G>A p.M448I | Missense Mutation (SNP) | VAF 17/324 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2
- CDH12 | c.1624G>T p.D542Y | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH12 | c.1048G>T p.A350S | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CDH7 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 45/375 reads (12%) | called by muse, mutect2, varscan2
- CFAP92 | c.1957C>A p.L653I | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- CHGB | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CIR1 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 33/485 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); called by muse, mutect2
- CLCN5 | c.401T>A p.F134Y | Missense Mutation (SNP) | VAF 27/429 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CLVS2 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 32/195 reads (16%) | called by muse, mutect2, varscan2
- COG3 | c.1309G>A p.D437N | Missense Mutation (SNP) | VAF 21/266 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2
- COLGALT1 | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | called by muse, varscan2
- CUBN | c.1516A>G p.T506A | Missense Mutation (SNP) | VAF 60/676 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.926); called by muse, mutect2
- CYLD | c.112C>T p.L38F | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.049); called by muse, mutect2
- DCDC2C | c.574G>T p.G192C | Missense Mutation (SNP) | VAF 59/331 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCUN1D4 | c.226T>C p.S76P | Missense Mutation (SNP) | VAF 26/382 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); called by muse, mutect2
- DENND5B | c.3711G>T p.E1237D | Missense Mutation (SNP) | VAF 19/259 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.107); called by muse, mutect2
- DGAT2L6 | c.773del p.G258Dfs*2 | Frame Shift Del (DEL) | VAF 61/490 reads (12%) | called by mutect2, pindel, varscan2
- DIS3L | c.2566G>C p.E856Q (on ENST00000319212 / NM_001143688.3; = p.E773Q on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.374); called by muse, mutect2
- DNAJC16 | c.1861G>T p.G621C | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DOCK4 | c.5272G>A p.E1758K | Missense Mutation (SNP) | VAF 42/618 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.119); called by muse, mutect2
- DRD3 | c.619G>T p.V207F | Missense Mutation (SNP) | VAF 52/320 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- DST | c.12106G>T p.G4036* (on ENST00000361203 / NM_001374722.1; = p.G1624* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 46/280 reads (16%) | called by muse, mutect2, varscan2
- DUS3L | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- DYNC1I1 | c.1541T>C p.V514A | Missense Mutation (SNP) | VAF 36/500 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- ERC2 | c.1216G>T p.A406S | Missense Mutation (SNP) | VAF 42/560 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.085); called by muse, mutect2
- FAAH2 | c.1511C>G p.A504G | Missense Mutation (SNP) | VAF 36/346 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- FLNB | c.7485G>C p.R2495S | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- FLNC | c.6265G>T p.E2089* | Nonsense Mutation (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- FREM3 | c.5128C>A p.H1710N | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); called by muse, varscan2
- GC | c.1204A>T p.K402* | Nonsense Mutation (SNP) | VAF 39/529 reads (7%) | called by muse, mutect2
- GDPD2 | c.1177G>T p.E393* | Nonsense Mutation (SNP) | VAF 20/298 reads (7%) | called by muse, mutect2
- GRIK1 | c.639G>T p.K213N | Missense Mutation (SNP) | VAF 43/323 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- H2BC7 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.052); called by muse, mutect2
- HAT1 | c.21G>T p.M7I | Missense Mutation (SNP) | VAF 27/275 reads (10%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2
- HCN1 | c.1891G>C p.E631Q | Missense Mutation (SNP) | VAF 87/771 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- HELB | c.906G>C p.K302N | Missense Mutation (SNP) | VAF 18/660 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2
- IMPA1 | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 40/715 reads (6%) | called by muse, mutect2
- INTS6L | c.514G>T p.V172L | Missense Mutation (SNP) | VAF 22/295 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- ITIH1 | c.1195A>T p.I399F | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- ITK | c.496-6C>A | Splice Region (SNP) | VAF 64/442 reads (14%) | called by muse, mutect2, varscan2
- ITSN1 | c.1176G>C p.E392D | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2
- KALRN | c.8575C>A p.L2859M (on ENST00000360013 / NM_001024660.4; = p.L1162M on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- KCTD9 | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); called by muse, mutect2
- LNPK | c.842C>G p.S281C | Missense Mutation (SNP) | VAF 32/320 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LRIG3 | c.2251C>G p.L751V | Missense Mutation (SNP) | VAF 55/1372 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2
- LRP1B | c.13579G>T p.G4527* | Nonsense Mutation (SNP) | VAF 54/394 reads (14%) | called by muse, mutect2, varscan2
- MAP7D2 | c.1627-1G>C p.X543_splice | Splice Site (SNP) | VAF 14/256 reads (5%) | called by muse, mutect2
- MED13L | c.3921G>T p.W1307C | Missense Mutation (SNP) | VAF 20/380 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- METTL24 | c.778C>A p.H260N | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- MGAM2 | c.2071G>T p.V691L | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- MOV10 | c.409G>T p.G137W | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MTREX | c.1347G>C p.K449N | Missense Mutation (SNP) | VAF 33/480 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); called by muse, mutect2
- MUC16 | c.15084G>T p.W5028C | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- MUC17 | c.6262G>A p.E2088K | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- MYT1L | c.1981C>G p.P661A | Missense Mutation (SNP) | VAF 37/290 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEBL | c.1741C>T p.Q581* | Nonsense Mutation (SNP) | VAF 34/612 reads (6%) | called by muse, mutect2
- NEXN | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 74/850 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- NFAT5 | c.2156G>C p.R719T | Missense Mutation (SNP) | VAF 29/468 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- NLRP3 | c.2662G>T p.G888W | Missense Mutation (SNP) | VAF 26/418 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); called by muse, mutect2
- NLRP7 | c.2044G>T p.V682L (on ENST00000340844 / NM_206828.3; = p.V654L on NM_139176.3) | Missense Mutation (SNP) | VAF 47/361 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NRDE2 | c.1696G>T p.D566Y | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- NUDCD2 | c.458C>G p.S153* | Nonsense Mutation (SNP) | VAF 14/171 reads (8%) | called by muse, mutect2
- OBI1 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 14/231 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.188); called by muse, mutect2
- OR13C5 | c.163C>A p.L55I | Missense Mutation (SNP) | VAF 21/245 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- OR52A1 | c.138G>T p.L46F | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- OR5AP2 | c.112C>G p.L38V | Missense Mutation (SNP) | VAF 18/346 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.437); called by muse, mutect2
- OR5B17 | c.724C>T p.H242Y | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.739); called by muse, mutect2
- OTOL1 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 32/470 reads (7%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.557); called by muse, mutect2
- PCDHGA2 | c.194G>C p.R65P | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PEG3 | c.1690G>T p.E564* | Nonsense Mutation (SNP) | VAF 20/322 reads (6%) | called by muse, mutect2
- PEX26 | c.842A>G p.Y281C | Missense Mutation (SNP) | VAF 11/202 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.277); called by muse, mutect2
- PLCB1 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 10/190 reads (5%) | called by muse, mutect2
- PLEKHF2 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 35/363 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.395); called by muse, mutect2
- PLXDC2 | c.1113C>A p.C371* | Nonsense Mutation (SNP) | VAF 17/312 reads (5%) | called by muse, mutect2
- PLXNC1 | c.3239C>A p.S1080Y | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- POTEC | c.383T>A p.F128Y | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.965); called by muse, mutect2
- PPP4R3A | c.1943G>C p.R648T (on ENST00000554943 / NM_001366432.1; = p.R635T on NM_001284280.1) | Missense Mutation (SNP) | VAF 58/550 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2
- PSG3 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.794); called by muse, mutect2
- PTPRC | c.1190T>A p.I397N | Missense Mutation (SNP) | VAF 100/824 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRO | c.1035G>T p.M345I | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RAB11FIP3 | c.1138G>C p.V380L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RASSF9 | c.606G>C p.K202N | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- RNASEL | c.1661C>T p.S554F | Missense Mutation (SNP) | VAF 32/544 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); called by muse, mutect2
- SENP7 | c.2845A>G p.T949A | Missense Mutation (SNP) | VAF 25/549 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2
- SLC25A13 | c.1329del p.I444Ffs*6 | Frame Shift Del (DEL) | VAF 79/706 reads (11%) | called by mutect2, pindel, varscan2
- SMYD4 | c.719A>G p.D240G | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.165); called by muse, mutect2
- SORL1 | c.4428C>A p.F1476L | Missense Mutation (SNP) | VAF 59/326 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPDYA | c.862C>A p.H288N | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2
- SRBD1 | c.374A>T p.H125L | Missense Mutation (SNP) | VAF 79/901 reads (9%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2
- STXBP2 | c.183C>G p.I61M | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- STYXL2 | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TAF1L | c.4873G>A p.E1625K | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.054); called by muse, mutect2
- TARDBP | c.706G>C p.D236H | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- TBC1D9 | c.2758C>T p.H920Y | Missense Mutation (SNP) | VAF 26/422 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.076); called by muse, mutect2
- TEX13C | c.862T>A p.W288R | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TFRC | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 93/469 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNR | c.2762_2763del p.T921Kfs*58 | Frame Shift Del (DEL) | VAF 28/262 reads (11%) | called by mutect2, pindel*
- TRIM3 | c.5C>G p.A2G | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- TRIP12 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.357); called by muse, mutect2
- TSC22D3 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 21/242 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TSGA10IP | c.731C>G p.S244* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- TTN | c.12022G>T p.G4008C (on ENST00000591111; = p.G3962C on NM_003319.4) | Missense Mutation (SNP) | VAF 19/251 reads (8%) | called by muse, mutect2
- USH2A | c.1282G>A p.G428R | Missense Mutation (SNP) | VAF 62/361 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- UTP14C | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 91/826 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- UTP4 | c.690G>T p.K230N | Missense Mutation (SNP) | VAF 32/436 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.052); called by muse, mutect2
- ZEB2 | c.2435A>T p.Q812L | Missense Mutation (SNP) | VAF 70/450 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ZFYVE26 | c.7187A>T p.Q2396L | Missense Mutation (SNP) | VAF 66/456 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZHX3 | c.1915G>C p.D639H | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.101); called by muse, mutect2
- ZNF112 | c.307C>A p.L103I (on ENST00000337401 / NM_001083335.2; = p.L97I on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF484 | c.1807A>G p.T603A | Missense Mutation (SNP) | VAF 41/329 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZNF527 | c.1726C>G p.H576D | Missense Mutation (SNP) | VAF 13/312 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ZNF611 | c.1600G>T p.G534* | Nonsense Mutation (SNP) | VAF 27/221 reads (12%) | called by muse, mutect2, varscan2
- ZNF727 | c.857G>A p.C286Y | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- ZNF804B | c.2136G>C p.L712F | Missense Mutation (SNP) | VAF 34/534 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0.047); called by muse, mutect2
- ZNF83 | c.1282G>T p.A428S | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ABI3 | c.543C>G p.T181= | Silent (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- ACAP1 | c.471T>A p.A157= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2, varscan2
- ADRA1D | c.570C>T p.I190= | Silent (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- ALK | c.2565G>A p.T855= | Silent (SNP) | VAF 29/141 reads (21%) | catalogued as rs752329968; ClinVar: likely benign; called by muse, mutect2, varscan2
- AR | c.1188C>A p.G396= | Silent (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- ARL14EPL | c.339G>A p.P113= | Silent (SNP) | VAF 30/434 reads (7%) | catalogued as rs75839405; called by muse, mutect2
- ASB12 | c.432C>G p.L144= | Silent (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- C11orf16 | c.465A>C p.P155= | Silent (SNP) | VAF 20/264 reads (8%) | called by muse, mutect2
- CACHD1 | c.2929C>T p.L977= | Silent (SNP) | VAF 15/262 reads (6%) | called by muse, mutect2
- CD79A | c.588C>T p.C196= | Silent (SNP) | VAF 16/200 reads (8%) | called by muse, mutect2
- CDC42BPA | c.1197T>C p.F399= | Silent (SNP) | VAF 10/209 reads (5%) | called by muse, mutect2
- COL6A2 | c.672C>A p.T224= | Silent (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- CSF2 | c.261C>T p.L87= | Silent (SNP) | VAF 22/178 reads (12%) | called by muse, mutect2, varscan2
- CYTH3 | c.150A>T p.T50= | Silent (SNP) | VAF 32/530 reads (6%) | called by muse, mutect2
- DACH2 | c.1462C>A p.R488= | Silent (SNP) | VAF 79/363 reads (22%) | catalogued as COSV64167874, COSV64174007; called by muse, mutect2, varscan2
- DAW1 | c.669C>A p.I223= | Silent (SNP) | VAF 32/303 reads (11%) | catalogued as COSV59363695; called by muse, mutect2, varscan2
- DDX11 | c.1545C>T p.Y515= | Silent (SNP) | VAF 15/171 reads (9%) | catalogued as rs149627310; called by muse, mutect2
- DLEC1 | c.1881G>T p.R627= | Silent (SNP) | VAF 12/197 reads (6%) | catalogued as COSV100343139; called by muse, mutect2
- DLX5 | c.210C>G p.L70= | Silent (SNP) | VAF 7/150 reads (5%) | called by muse, mutect2
- DPRX | c.75G>A p.K25= | Silent (SNP) | VAF 20/179 reads (11%) | called by muse, mutect2, varscan2
- EYS | c.5262G>T p.P1754= | Silent (SNP) | VAF 46/234 reads (20%) | catalogued as COSV100426075; called by muse, mutect2, varscan2
- GPATCH8 | c.1479G>A p.Q493= | Silent (SNP) | VAF 8/152 reads (5%) | called by muse, mutect2
- H3C11 | c.288T>C p.A96= | Silent (SNP) | VAF 17/244 reads (7%) | called by muse, mutect2
- HCN1 | c.2508G>T p.P836= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV57495249; called by muse, mutect2, varscan2
- HCN1 | c.1371G>C p.L457= | Silent (SNP) | VAF 18/323 reads (6%) | catalogued as rs561869170, COSV57491077, COSV57497442, COSV57503513; called by muse, mutect2
- HDLBP | c.2184C>T p.F728= | Silent (SNP) | VAF 13/116 reads (11%) | catalogued as COSV100190289; called by muse, varscan2
- HERC2 | c.8349C>A p.S2783= | Silent (SNP) | VAF 9/138 reads (7%) | called by muse, mutect2
- ILDR2 | c.1047C>T p.F349= | Silent (SNP) | VAF 48/464 reads (10%) | catalogued as COSV54830325; called by muse, mutect2, varscan2
- INSR | c.1749C>G p.L583= | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as COSV57164651; called by muse, mutect2
- KCNMB4 | c.481C>T p.L161= | Silent (SNP) | VAF 21/746 reads (3%) | called by muse, mutect2
- KEL | c.684A>G p.P228= | Silent (SNP) | VAF 30/450 reads (7%) | called by muse, mutect2
- KLK5 | c.444T>A p.P148= | Silent (SNP) | VAF 26/245 reads (11%) | catalogued as rs878990035; called by muse, mutect2, varscan2
- KRAS | c.36T>A p.G12= | Silent (SNP) | VAF 81/545 reads (15%) | catalogued as COSV55510792, COSV55573999, COSV55588748; called by muse, mutect2, varscan2
- KRT85 | c.573G>C p.G191= | Silent (SNP) | VAF 14/290 reads (5%) | called by muse, mutect2
- LAMB2 | c.4173C>T p.G1391= | Silent (SNP) | VAF 26/228 reads (11%) | called by muse, mutect2, varscan2
- LMO3 | c.252C>T p.I84= | Silent (SNP) | VAF 30/540 reads (6%) | catalogued as rs767665466, COSV53785268; called by muse, mutect2
- MGAM | c.1131G>T p.A377= | Silent (SNP) | VAF 20/325 reads (6%) | catalogued as COSV101527453; called by muse, mutect2
- MON2 | c.1737G>A p.E579= | Silent (SNP) | VAF 17/232 reads (7%) | called by muse, mutect2
- MUC12 | c.1947A>T p.T649= (on ENST00000379442; = p.T506= on NM_001164462.1) | Silent (SNP) | VAF 12/132 reads (9%) | called by muse, mutect2
- MUC12 | c.3369C>T p.A1123= (on ENST00000379442; = p.A980= on NM_001164462.1) | Silent (SNP) | VAF 29/253 reads (11%) | called by muse, mutect2, varscan2
- MYPN | c.3108A>T p.V1036= | Silent (SNP) | VAF 56/696 reads (8%) | catalogued as COSV62732700; called by muse, mutect2
- NFATC2 | c.696G>T p.L232= | Silent (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- OR14C36 | c.228C>T p.V76= | Silent (SNP) | VAF 35/204 reads (17%) | catalogued as rs267598504; called by muse, mutect2, varscan2
- OTUB2 | c.60G>T p.R20= | Silent (SNP) | VAF 17/243 reads (7%) | called by muse, mutect2
- PLCE1 | c.2877G>A p.Q959= | Silent (SNP) | VAF 22/392 reads (6%) | catalogued as rs376245704; called by muse, mutect2
- PLCE1 | c.5890C>A p.R1964= | Silent (SNP) | VAF 54/752 reads (7%) | catalogued as rs775052849, COSV53368895; called by muse, mutect2
- PTCH2 | c.2508C>T p.F836= | Silent (SNP) | VAF 10/119 reads (8%) | catalogued as rs1267534771; called by muse, mutect2
- RAPGEF5 | c.636A>C p.S212= (on ENST00000401957 / NM_001367602.2; = p.S515= on NM_012294.5) | Silent (SNP) | VAF 29/534 reads (5%) | called by muse, mutect2
- RBM39 | c.1182T>C p.S394= | Silent (SNP) | VAF 63/556 reads (11%) | called by muse, varscan2
- RNF103 | c.723A>C p.A241= | Silent (SNP) | VAF 46/480 reads (10%) | called by muse, mutect2
- RNF19A | c.1746C>T p.V582= | Silent (SNP) | VAF 44/572 reads (8%) | called by muse, mutect2
- SERPINF1 | c.9C>T p.A3= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as rs918581134; called by muse, mutect2
- SLC26A4 | c.1533G>A p.L511= | Silent (SNP) | VAF 27/572 reads (5%) | catalogued as rs745508336; called by muse, mutect2
- SLC4A4 | c.1824A>T p.A608= (on ENST00000264485 / NM_001098484.3; = p.A564= on NM_003759.4) | Silent (SNP) | VAF 20/314 reads (6%) | called by muse, mutect2
- SLC5A1 | c.1725G>A p.A575= | Silent (SNP) | VAF 46/585 reads (8%) | catalogued as rs368853644; ClinVar: uncertain significance; called by muse, mutect2
- SORCS1 | c.3453C>A p.A1151= | Silent (SNP) | VAF 24/380 reads (6%) | catalogued as COSV53894269; called by muse, mutect2
- SOX5 | c.766C>T p.L256= | Silent (SNP) | VAF 38/528 reads (7%) | catalogued as COSV58622942; called by muse, mutect2
- SRCIN1 | c.618C>T p.A206= (on ENST00000621492; = p.A172= on NM_025248.3) | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- STMND1 | c.465C>G p.L155= | Silent (SNP) | VAF 17/456 reads (4%) | called by muse, mutect2
- TEF | c.801C>T p.F267= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as rs1386581771; called by muse, mutect2
- TPO | c.189G>A p.K63= | Silent (SNP) | VAF 24/331 reads (7%) | catalogued as COSV61102285; called by muse, mutect2
- TRIM72 | c.516G>C p.V172= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs150176391; called by muse, mutect2, varscan2
- UGT1A9 | c.144C>G p.L48= | Silent (SNP) | VAF 14/212 reads (7%) | catalogued as COSV60840663; called by muse, mutect2
- UQCRFS1 | c.492C>T p.N164= | Silent (SNP) | VAF 51/429 reads (12%) | catalogued as rs1371159478; called by muse, mutect2, varscan2
- USF3 | c.1362G>T p.V454= | Silent (SNP) | VAF 15/264 reads (6%) | called by muse, mutect2
- USP48 | c.1323T>C p.D441= | Silent (SNP) | VAF 43/256 reads (17%) | called by muse, mutect2, varscan2
- ZNF135 | c.1689C>T p.S563= (on ENST00000313434 / NM_001289401.2; = p.S575= on NM_003436.4) | Silent (SNP) | VAF 20/279 reads (7%) | called by muse, mutect2
- ZNF679 | c.843A>T p.S281= | Silent (SNP) | VAF 23/141 reads (16%) | called by muse, mutect2, varscan2
- ZNF705A | c.336G>T p.L112= | Silent (SNP) | VAF 20/474 reads (4%) | called by muse, mutect2
- ZNF729 | c.894C>A p.G298= | Silent (SNP) | VAF 12/296 reads (4%) | called by muse, mutect2
- ZNF729 | c.1758C>A p.A586= | Silent (SNP) | VAF 36/496 reads (7%) | called by muse, mutect2
- ABAT | c.70+47C>A | Intron (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848332 C>A | 5'Flank (SNP) | VAF 51/229 reads (22%) | called by muse, mutect2, varscan2
- ATP6V0D1 | c.303-1202C>A | Intron (SNP) | VAF 14/99 reads (14%) | called by muse, mutect2
- ATRNL1 | c.3795+48122C>T | Intron (SNP) | VAF 8/158 reads (5%) | catalogued as rs1023988851; called by muse, mutect2
- BRINP2 | c.461-73G>T | Intron (SNP) | VAF 17/189 reads (9%) | called by muse, mutect2
- C19orf84 | c.-8C>T | 5'UTR (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- CCDC196 | c.716-1821C>A | Intron (SNP) | VAF 58/430 reads (13%) | called by muse, mutect2, varscan2
- CD8A | c.*34G>A | 3'UTR (SNP) | VAF 40/578 reads (7%) | catalogued as rs1418471499; called by muse, mutect2
- COL6A6 | c.4533+14C>A | Intron (SNP) | VAF 19/151 reads (13%) | called by muse, mutect2, varscan2
- ERVV-1 | chr19:53010088 G>T | 5'Flank (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2, varscan2
- ETV2 | c.829-19G>T | Intron (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- FOXP2 | c.*2212G>T | 3'UTR (SNP) | VAF 63/568 reads (11%) | called by muse, mutect2, varscan2
- GANAB | c.*600C>T | 3'UTR (SNP) | VAF 26/336 reads (8%) | called by muse, mutect2
- GUSBP10 | n.282G>T | RNA (SNP) | VAF 29/169 reads (17%) | catalogued as rs568514970; called by muse, mutect2, varscan2
- GYS2 | c.-35G>T | 5'UTR (SNP) | VAF 42/279 reads (15%) | called by muse, mutect2, varscan2
- HSD17B7P2 | n.139C>G | RNA (SNP) | VAF 21/158 reads (13%) | called by muse, mutect2, varscan2
- KCNT2 | c.2910+7384G>T | Intron (SNP) | VAF 81/729 reads (11%) | called by muse, mutect2, varscan2
- KRT5 | c.1219-41C>G | Intron (SNP) | VAF 29/281 reads (10%) | called by muse, mutect2
- LINC02872 | n.391G>A | RNA (SNP) | VAF 30/340 reads (9%) | called by muse, mutect2
- LPP | c.1240+27G>A | Intron (SNP) | VAF 20/162 reads (12%) | catalogued as COSV100447700; called by muse, mutect2, varscan2
- MAGEB16 | c.-66-1596G>C | Intron (SNP) | VAF 20/338 reads (6%) | called by muse, mutect2
- MEMO1 | c.213-2819C>T | Intron (SNP) | VAF 20/198 reads (10%) | called by muse, mutect2, varscan2
- MIA2 | c.1887+90C>T | Intron (SNP) | VAF 33/228 reads (14%) | called by muse, mutect2, varscan2
- MMP25 | c.1006+9T>A | Intron (SNP) | VAF 9/87 reads (10%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+92846C>A | Intron (SNP) | VAF 24/140 reads (17%) | called by muse, mutect2, varscan2
- MRPL34 | chr19:17305839 C>G | 5'Flank (SNP) | VAF 13/116 reads (11%) | called by muse, mutect2, varscan2
- NDUFA10 | c.547+735C>T | Intron (SNP) | VAF 15/140 reads (11%) | catalogued as rs1328870760; called by muse, mutect2, varscan2
- PAX7 | c.1402+35del | Intron (DEL) | VAF 11/74 reads (15%) | called by mutect2, pindel, varscan2
- RAF1 | c.-2C>A | 5'UTR (SNP) | VAF 32/470 reads (7%) | called by muse, mutect2
- RIC8A | c.-27G>T | 5'UTR (SNP) | VAF 7/34 reads (21%) | catalogued as rs1292922327; called by muse, mutect2
- RNF5P1 | n.337T>C | RNA (SNP) | VAF 12/244 reads (5%) | called by muse, mutect2
- SATL1 | c.-122G>T | 5'UTR (SNP) | VAF 15/220 reads (7%) | catalogued as rs747862365; called by muse, mutect2
- SEM1 | c.*1C>G | 3'UTR (SNP) | VAF 40/415 reads (10%) | called by muse, mutect2
- TMPRSS6 | c.-1-15C>A | Intron (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- ZNF454 | c.-46C>T | 5'UTR (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2, varscan2
- ZNF99 | c.*74A>T | 3'UTR (SNP) | VAF 33/287 reads (11%) | catalogued as COSV101233788; called by muse, mutect2, varscan2
